Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3UF, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3UF-01A (Primary Tumor).

[page 1 of 5]
* Amended *

Patient: [REDACTED]

Physician:
CC:

Patient Address: [REDACTED]

Date of Receipt:
Date of Amendment:

1CD-0-3

Leiomyosarcoma, Nos 8890/3

CQCF Site: Retroperitoneum C48.0

Path: Vena Cava, inferior C49.4

hw
5/23/12

Clinical Diagnosis & History:

Specimens Submitted:

- 1: SP: Inferior vena cava with tumor
- 2: SP: Gallbladder
- 3: SP: Iliac lymph node
- 4: SP: Paracaval lymph node

AMENDED DIAGNOSIS:

1. INFERIOR VENA CAVA; RESECTION:
- RESIDUAL LEIOMYOSARCOMA. HIGH GRADE, INVOLVING INFERIOR VENA CAVA
- THE TUMOR CONSISTS OF 2 NODULES, MEASURING 3.7 AND 2.9 CM IN GREATEST DIMENSIONS.
- MITOSES: >10/10 HPFS.
- FOCAL NECROSIS IS PRESENT.
- TUMOR IS PRESENT AT THE SOFT TISSUE MARGIN INCLUDING STAPLED MARGIN AND AT WALL OF INFERIOR VENA CAVAL MARGIN CLOSE TO TUMOR.
- THE OTHER VENOUS RESECTION MARGIN IS NEGATIVE.
- FOUR BENIGN LYMPH NODES (0/4)
2. GALLBLADDER, RESECTION:
- CHRONIC CHOLECYSTITIS AND CHOLESTEROSIS.
3. LYMPH NODE, ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
4. LYMPH NODE, PARACAVAL, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

Note: Reason for amendment: As per additional clinical information (the patient has residual leiomyosarcoma and not a recurrent leiomyosarcoma. The amended report above reflects this change (from "recurrent leiomyosarcoma" to "residual leiomyosarcoma").

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED

** Continued on next page **

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Accession #: [REDACTED]

Page 2 of 5

THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "inferior vena cava with tumor" and consists of a 9.4 cm patent segment of vein, associated with a 6.0 x 2.8 x 2.9 cm nodular mass at one end. The nodular mass is inked black and white and consists of two separate adjacent nodules, measuring 3.7 x 2.8 x 2.9 cm and 2.9 x 1.9 x 2.2 cm, respectively. There is a 1.3 cm staple line associated with a thin piece of yellow plastic on the larger nodule. This staple line is inked blue. Sectioning of the mass shows predominantly white, whorled cut surfaces. There are focal areas of nodularity. Sectioning also shows both nodules to be subjacent to the vein. The segment of vein that is not involved by this mass measures 6.2 x 0.7 cm. There is a separate 1.7 x 1.2 x 0.8 cm nodule that is loosely attached to the larger nodule by fibrous tissue. Cut sections of this nodule shows gray - tan solid, cut surfaces. Tissue is submitted for TPS. Photographs are taken. Representative sections are submitted.

Summary of sections:

DM - vein margin distal to tumor
TM - staple margin to tumor
CM - vein margin closer to tumor
LN - large nodule
SN - small nodule
N - separate nodule

(YXZ)

2). The specimen is received fresh, labeled "Gallbladder" and consists of a gallbladder measuring 8.0 x 2.0 x 1.0 cm. The surface of the gallbladder is tan, green and smooth. It is opened to reveal yellow green viscous bile and tan green sparkled mucosa. The wall thickness measures up to 0.3 cm. Representative sections including the cystic duct margin are submitted.

Summary of sections:

M - cystic duct margin
U - undesignated

3). The specimen is received in formalin, labeled "iliac lymph node" and consists of one pink tan firm lymph node measuring 1.1 x 0.7 x 0.6 cm. The lymph nodes is bisected and submitted entirely.

Summary of sections:

BLN-- bisected lymph nodes

** Continued on next page **

[page 3 of 5]
Page 3 of 5

Summary of sections:
BLN-- bisected lymph nodes

Summary of Sections:
Part 1: SP: Inferior vena cava with tumor

Part 2: SP: Gallbladder

Part 3: SP: Iliac lymph node

Part 4: SP: Paracaval lymph node

Amendments

Amend Date: Amended By:

** Continued on next page **

[page 4 of 5]
_____ of Report:

Page 4 of 5

Original Diagnosis:

5. INFERIOR VENA CAVA; RESECTION:
- RECURRENT LEIOMYOSARCOMA. HIGH GRADE, INVOLVING INFERIOR VENA CAVA
- THE TUMOR CONSISTS OF 2 NODULES, MEASURING 3.7 AND 2.9 CM IN GREATEST DIMENSIONS.
- MITOSES: >10/10 HPFS.
- FOCAL NECROSIS IS PRESENT.
- TUMOR IS PRESENT AT THE SOFT TISSUE MARGIN INCLUDING STAPLED MARGIN AND AT WALL OF INFERIOR VENA CAVAL MARGIN CLOSE TO TUMOR.
- THE OTHER VENOUS RESECTION MARGIN IS NEGATIVE.
- FOUR BENIGN LYMPH NODES (0/4)
6. GALLBLADDER, RESECTION:
- CHRONIC CHOLECYSTITIS AND CHOLESTEROLOSIS.
7. LYMPH NODE, ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
8. LYMPH NODE, PARACAVAL, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

*** Report Electronically Signed Out ***
Signed out by

Intraoperative Consultation:

This document represents an amended version of the surgical pathology report originally issued on . That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:

DIAGNOSIS:

1. INFERIOR VENA CAVA; RESECTION:
- RECURRENT LEIOMYOSARCOMA. HIGH GRADE, INVOLVING INFERIOR VENA CAVA

AMENDED REPORT:

DIAGNOSIS:

1. INFERIOR VENA CAVA; RESECTION:
- RESIDUAL LEIOMYOSARCOMA. HIGH GRADE, INVOLVING INFERIOR VENA
CAVA

Referring Physician Contacted

office was notified by Pathology via E-mail on

This document represents an amended version of the surgical pathology report

** Continued on next page **

[page 5 of 5]
SURGICAL

Date of Report:

----- Page 5 of 5
originally issued on That report is superseded by the present
document. The amendment consists of the following change:

ORIGINAL REPORT:

DIAGNOSIS:

1. INFERIOR VENA CAVA; RESECTION:
- RECURRENT LEIOMYOSARCOMA. HIGH GRADE, INVOLVING INFERIOR VENA
CAVA

AMENDED REPORT:

DIAGNOSIS:

1. INFERIOR VENA CAVA; RESECTION:
- RESIDUAL LEIOMYOSARCOMA. HIGH GRADE, INVOLVING INFERIOR VENA
CAVA

** End of Report **

11/12/12

Source: NCI Genomic Data Commons file d6a10e3b-777e-4878-af2a-a860daac3a06 (TCGA-DX-A3UF.F73129F2-A892-4C83-AF9A-DE979DA7D5F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).